FM case AD10305 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/d87e165f-2279-49fd-b3a2-02547546f24d

Male, 74.2 years: Renal cell carcinoma, NOS (ICD-O-3 8312/3) of the kidney; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
